Gene-level copy-number profile of tumor specimen TCGA-RQ-AAAT-01A from TCGA case TCGA-RQ-AAAT, project TCGA-DLBC (Lymphoid Neoplasm Diffuse Large B-cell Lymphoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Primary diffuse large B-cell lymphoma of the CNS; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 63.5 years (23,178 days).
Specimen TCGA-RQ-AAAT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-DLBC.bbe9854a-d1df-4487-9f90-3fe8dc9d93e2.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-RQ-AAAT-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/37fd3938-1a3a-48b3-a05e-fd36dbf77a79

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 192; copy number 1: 58; copy number 2: 5,675; copy number 3: 14,354; copy number 4: 33,378; copy number 5: 1,302; copy number 6: 4,427; copy number 7: 252; copy number 8: 11; copy number 9: 3; copy number 10: 69; copy number 12: 33; copy number 13: 3; copy number 14: 5; copy number 16: 40; copy number 21: 10.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-RQ-AAAT-01A-11D-A38W-01): tumor purity 0.7, ploidy 3.74, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 192 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:105,764,503–106,369,546, 104 genes (broad region; genes not listed).
- chr15:41,621,224–41,773,081, 3 genes (within-gene range 0–4): MGA, AC073657.2, AC073657.1.
- chr22:22,322,472–22,906,803, 85 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 163 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:168,695,874–169,103,276, 1 gene, copy number 21 (within-gene range 4–21): AL135926.1.
- chr1:168,898,136–170,739,421, 43 genes, copy number 10–21: SUMO1P2, AL135926.2, LINC00970, RPL29P7, AL031726.2, RNA5SP66, AL031726.1, ATP1B1, NME7, Z99758.1, BLZF1, CCDC181, SLC19A2, AL021068.1, Z99572.1, F5, SELP, C1orf112, SELL, SELE, AL021940.1, METTL18, SCYL3, RN7SL333P, AL031297.1, KIFAP3, RN7SL269P, MRPS10P1, AL356475.1, SIGLEC30P, METTL11B, MIR3119-2, MIR3119-1, LINC01681, ISCUP1, LINC01142, HAUS4P1, GORAB-AS1, GORAB, AL162399.1, AL023495.1, PRRX1, Z97200.1.
- chr2:56,750,300–57,380,132, 3 genes, copy number 9 (within-gene range 4–9): PPIAP63, EIF2S2P7, AC132153.1.
- chr2:60,450,520–61,888,671, 44 genes, copy number 14–16 (within-gene range 5–16): BCL11A, AC009970.1, RN7SL361P, IFITM3P9, RPL26P13, RNU6-612P, ATP1B3P1, PAPOLG, LINC01185, RN7SL632P, RPL21P33, REL, RNU4-51P, AC010733.1, NONOP2, RPS12P3, PUS10, RNA5SP95, PEX13, KIAA1841, AC016747.4, AC016747.1, C2orf74, AC016747.2, AHSA2P, USP34, AC016747.3, AC018889.1, AC016894.1, SNORA70B, AC016727.1, XPO1, AC016727.3, AC016727.2, RPS29P10, RNU6-1145P, AC108039.1, RPS24P7, AC108039.2, FAM161A, AC107081.2, CCT4, AC107081.1, AC107081.3.
- chr2:61,928,634–61,928,704, 1 gene, copy number 14: Y_RNA.
- chr2:229,357,629–229,714,555, 1 gene, copy number 13 (within-gene range 4–13): DNER.
- chr2:229,606,238–229,702,148, 2 genes, copy number 13: RNU7-9P, AC007559.1.
- chr2:237,627,587–238,926,269, 33 genes, copy number 12 (within-gene range 8–12): LRRFIP1, AC012076.1, RBM44, RAMP1, SNORD39, UBE2F, UBE2F-SCLY, RNU6-1333P, SCLY, ESPNL, KLHL30, KLHL30-AS1, ERFE, ILKAP, LINC02610, AC012485.1, HES6, PER2, AC012485.3, AC012485.2, TRAF3IP1, RNU6-234P, ASB1, AC016999.1, AC016999.2, LINC01107, LINC01937, AC113618.2, AC113618.1, AC145625.2, AC145625.1, TWIST2, LINC01940.
- chr17:21,614,487–22,706,703, 35 genes, copy number 10 (within-gene range 6–10): AC233702.1, AC233702.4, AC233702.9, KCNJ18, AC243725.1, ABBA01006766.1, NCOR1P2, UBBP4, FTLP13, LINC02002, AC138761.1, AC138761.2, FAM27E5, AC087575.1, FLJ36000, AC132825.3, AC132825.4, MTND6P35, MTCYBP13, MTRNR2L1, AC132825.2, MTND1P15, MTND2P13, AC132825.1, NMTRS-TGA3-1, MTATP6P3, MTCO3P13, AC132825.6, AC132825.7, AC132825.5, AC131055.2, AC131055.1, AC131274.3, AC131274.1, AC131274.2.

Autosomal genes at a single copy (total copy number 1): 58. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
